Somatic mutation profile of tumor specimen TCGA-AB-2840-03B (aliquot TCGA-AB-2840-03B-01W-0728-08) from TCGA case TCGA-AB-2840, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute promyelocytic leukaemia, t(15;17)(q22;q11-12); Tissue or organ of origin: Bone marrow; Age at diagnosis: 74.6 years (27,243 days).
Specimen TCGA-AB-2840-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 294fb317-5ed4-491a-b85a-38b311453d06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2840-11B (Solid Tissue Normal), aliquot TCGA-AB-2840-11B-01W-0729-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3eb19c8f-ce15-4f88-9cca-7459c0716b1d

The open-access MAF lists 19 somatic variants for this specimen: 11 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 10, Silent 8, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM166C | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 1049/1125 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56600426; called by muse, mutect2, varscan2
- FOLR3 | c.9G>A p.M3I | Missense Mutation (SNP) | VAF 32/723 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.067); catalogued as rs1488003191; called by muse, mutect2
- SH2D2A | c.1154T>A p.L385H | Missense Mutation (SNP) | VAF 74/915 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV63884551; called by muse, mutect2
- TM9SF1 | c.1427+1G>A p.X476_splice | Splice Site (SNP) | VAF 16/192 reads (8%) | catalogued as rs762189222; called by muse, mutect2
- ANKRD53 | c.841A>G p.K281E | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); called by muse, mutect2
- BEND7 | c.614A>T p.E205V | Missense Mutation (SNP) | VAF 12/366 reads (3%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.587); called by muse, mutect2
- C1orf127 | c.988G>C p.V330L | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.116); called by muse, mutect2
- CCL16 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 29/1056 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); called by muse, mutect2
- CHMP3 | c.37A>G p.K13E | Missense Mutation (SNP) | VAF 30/762 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.037); called by muse, mutect2
- CRISP3 | c.633A>T p.R211S (on ENST00000371159 / NM_001368123.1; = p.R193S on NM_006061.4) | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.381); called by muse, mutect2
- PAG1 | c.239G>A p.S80N | Missense Mutation (SNP) | VAF 17/552 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.168); called by muse, mutect2
- ANK2 | c.765G>T p.R255= | Silent (SNP) | VAF 10/164 reads (6%) | catalogued as COSV100004091, COSV52157098, COSV52171040; called by muse, mutect2
- ETNK2 | c.507C>T p.P169= | Silent (SNP) | VAF 455/470 reads (97%) | catalogued as rs763600102, COSV65820639; called by muse, mutect2, varscan2
- HIP1 | c.2394G>A p.T798= | Silent (SNP) | VAF 22/642 reads (3%) | catalogued as rs375108590; called by muse, mutect2
- NOM1 | c.565C>T p.L189= | Silent (SNP) | VAF 13/278 reads (5%) | called by muse, mutect2
- NPRL2 | c.204T>C p.P68= | Silent (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- RPL14 | c.522A>G p.P174= | Silent (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2
- SH2D2A | c.834T>C p.P278= | Silent (SNP) | VAF 106/1854 reads (6%) | catalogued as rs1240323583; called by muse, mutect2
- TLN1 | c.2100C>T p.T700= | Silent (SNP) | VAF 34/508 reads (7%) | catalogued as rs772366606; called by muse, mutect2
